Gene-level copy-number profile of tumor specimen ALCH-B04N-TTP1-A from ALCHEMIST case ALCH-B04N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.8 years (27,692 days).
Specimen ALCH-B04N-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f64e486e-c519-4a94-9bc6-33d0f05d8e2e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B04N-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/63723c2d-8d29-4396-9c68-1e643ae3b5b1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 7,530; copy number 2: 47,605; copy number 3: 3,699; copy number 4: 64; copy number 24: 1; copy number 63: 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,205,988–3,208,664, 1 gene (within-gene range 0–1): AL512383.1.
- chr1:143,766,540–143,825,837, 5 genes: FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1.
- chr7:98,214,624–98,252,232, 1 gene: TECPR1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:43,414,483–43,427,131, 1 gene, copy number 24: SIK1.
- chr21:43,461,960–43,479,534, 1 gene, copy number 63 (within-gene range 3–63): LINC00313.

Autosomal genes at a single copy (total copy number 1): 4,696. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
